Gene-level copy-number profile of tumor specimen TCGA-UE-A6QU-01A from TCGA case TCGA-UE-A6QU, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleomorphic liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-UE-A6QU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.58a9fc52-af4d-4f80-9a14-235faf1dfb46.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UE-A6QU-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d2f7561e-56c6-4ecd-a100-25a14471dfbb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,888; copy number 2: 24,750; copy number 3: 19,285; copy number 4: 9,433; copy number 5: 1,360; copy number 6: 1,063; copy number 7: 165; copy number 8: 101; copy number 9: 347; copy number 10: 52; copy number 11: 22; copy number 13: 112; copy number 14: 13; copy number 15: 114; copy number 17: 105; copy number 18: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UE-A6QU-01A-12D-A32H-01): tumor purity 0.36, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,044,883–196,065,235, 1 gene: LINC01724.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,212 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:169,662,007–169,854,080, 1 gene, copy number 5 (within-gene range 2–5): C1orf112.
- chr1:169,722,640–175,045,648, 117 genes, copy number 5 (broad region; genes not listed).
- chr2:98,997,261–100,192,428, 15 genes, copy number 5 (within-gene range 4–5): TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B, REV1, AC018690.1, AFF3.
- chr3:73,648,399–88,601,402, 120 genes, copy number 6–18 (broad region; genes not listed).
- chr4:44,533,615–60,038,586, 216 genes, copy number 5–8 (broad region; genes not listed).
- chr5:15,500,180–15,939,795, 1 gene, copy number 5 (within-gene range 4–5): FBXL7.
- chr5:15,935,182–18,049,872, 64 genes, copy number 5 (broad region; genes not listed).
- chr5:24,352,309–45,895,970, 321 genes, copy number 6–17 (broad region; genes not listed).
- chr5:52,787,916–52,959,209, 1 gene, copy number 7 (within-gene range 2–7): ITGA1.
- chr5:52,889,666–54,645,987, 28 genes, copy number 6–7: B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1.
- chr5:106,543,066–115,088,475, 90 genes, copy number 6–9 (broad region; genes not listed).
- chr5:123,468,781–124,438,625, 6 genes, copy number 6 (within-gene range 2–6): HMGB3P17, AC026422.1, CSNK1G3, KRT18P16, LINC01170, HMGB1P29.
- chr5:179,550,554–181,342,213, 89 genes, copy number 8 (broad region; genes not listed).
- chr6:70,566,917–71,534,715, 25 genes, copy number 5: SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2.
- chr7:102,748,971–103,989,658, 26 genes, copy number 7 (within-gene range 4–7): FAM185A, AC105052.2, FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86.
- chr7:116,237,929–117,874,139, 47 genes, copy number 5 (within-gene range 3–5): AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2.
- chr8:37,934,281–39,105,445, 43 genes, copy number 5: GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D.
- chr8:39,157,538–39,158,701, 1 gene, copy number 5: RPL3P10.
- chr8:62,110,524–63,014,000, 8 genes, copy number 6 (within-gene range 3–6): NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4.
- chr8:99,804,159–101,262,903, 45 genes, copy number 5–7: AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844.
- chr8:121,113,358–126,558,478, 102 genes, copy number 5 (broad region; genes not listed).
- chr11:117,427,772–117,929,459, 9 genes, copy number 6 (within-gene range 2–6): DSCAML1, AP000711.1, AP001554.1, FXYD2, AP000757.2, FXYD6-FXYD2, AP000757.1, FXYD6, TMPRSS13.
- chr14:101,730,437–106,875,071, 341 genes, copy number 9 (broad region; genes not listed).
- chr15:26,115,726–26,477,840, 4 genes, copy number 5: LINC00929, AC012060.1, LINC02248, AC009878.2.
- chr15:26,557,598–26,557,937, 1 gene, copy number 5: AC009878.1.
- chr17:7,717,354–18,842,364, 365 genes, copy number 5–6 (broad region; genes not listed).
- chr17:18,840,618–18,840,920, 1 gene, copy number 5: RN7SL627P.
- chr17:18,943,999–22,706,703, 192 genes, copy number 5 (broad region; genes not listed).
- chr18:39,206,917–39,800,322, 1 gene, copy number 5 (within-gene range 4–5): MIR924HG.
- chr18:39,334,872–46,759,257, 66 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:11,925,075–11,979,290, 1 gene, copy number 5 (within-gene range 4–5): AC008770.2.
- chr19:11,965,037–15,145,318, 191 genes, copy number 5 (broad region; genes not listed).
- chr20:15,619,494–16,573,448, 5 genes, copy number 7 (within-gene range 3–7): ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B.
- chr20:37,178,410–64,313,132, 666 genes, copy number 6 (broad region; genes not listed).
- chr21:19,759,359–20,258,820, 3 genes, copy number 6: C1QBPP1, LINC01683, LINC02573.

Autosomal genes at a single copy (total copy number 1): 2,851. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
